Gene-level copy-number profile of tumor specimen MP2PRT-PAVLRL-TMP1-A from MP2PRT case MP2PRT-PAVLRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,541 days).
Specimen MP2PRT-PAVLRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca504790-690e-4b30-bc29-f9e58fe83f6e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVLRL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/bfe2e82c-f697-41a6-b061-e93d24355296

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 245; copy number 1: 3,218; copy number 2: 55,412; copy number 3: 25.

Homozygous deletions (total copy number 0; autosomes only): 245 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 41 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:89,959,979–89,990,221, 4 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr14:22,132,553–22,552,156, 90 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr22:22,032,745–22,215,270, 20 genes (within-gene range 0–1): IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2.
- chr22:22,420,326–22,905,025, 67 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
